Somatic mutation profile of tumor specimen MP2PRT-PATAEZ-TMP1-A (aliquot MP2PRT-PATAEZ-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PATAEZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.0 years (2,203 days).
Specimen MP2PRT-PATAEZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59bc6028-90e5-40d3-9433-eae6aac885e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATAEZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATAEZ-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14484730-71c5-410f-9c92-724628a32399

The open-access MAF lists 226 somatic variants for this specimen: 166 protein-altering or splice-affecting, 49 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 140, Silent 49, Nonsense Mutation 21, Intron 8, Splice Site 2, Splice Region 2, Frame Shift Del 1, 5'UTR 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APTX | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 61/288 reads (21%) | catalogued as rs201912053, COSV58929095; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EED | c.707G>C p.R236T | Missense Mutation (SNP) | VAF 56/414 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1131692176, COSV54557802; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.2593G>C p.E865Q | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.756); catalogued as COSV101329961, COSV70027848; called by muse, mutect2, varscan2
- AK7 | c.54G>C p.Q18H | Missense Mutation (SNP) | VAF 53/343 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV99967579; called by muse, mutect2, varscan2
- AKR7L | c.331C>G p.L111V | Missense Mutation (SNP) | VAF 76/394 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV70167657; called by muse, mutect2, varscan2
- ARMC3 | c.1972G>C p.E658Q | Missense Mutation (SNP) | VAF 40/445 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.69); catalogued as COSV53056960, COSV99035369; called by muse, mutect2
- AUTS2 | c.1846G>A p.D616N | Missense Mutation (SNP) | VAF 51/351 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as rs756334229; called by muse, mutect2, varscan2
- BARD1 | c.1127C>G p.S376* | Nonsense Mutation (SNP) | VAF 74/412 reads (18%) | catalogued as COSV53618988; called by muse, mutect2, varscan2
- BCHE | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 35/250 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200998515, CM034212; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BIRC6 | c.4616C>G p.S1539* | Nonsense Mutation (SNP) | VAF 6/194 reads (3%) | catalogued as COSV101429135; called by muse, mutect2
- BTN3A3 | c.1077G>C p.Q359H | Missense Mutation (SNP) | VAF 28/225 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); catalogued as COSV55071713; called by muse, mutect2, varscan2
- CDH7 | c.1667C>T p.S556L | Missense Mutation (SNP) | VAF 51/301 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV59888426; called by muse, mutect2, varscan2
- CEP162 | c.3128G>C p.R1043T | Missense Mutation (SNP) | VAF 46/320 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); catalogued as COSV57619182; called by muse, mutect2, varscan2
- CYTH3 | c.1181G>A p.R394Q (on ENST00000396741; = p.R393Q on NM_004227.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/405 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs780996917, COSV60364287; called by muse, mutect2, varscan2
- DST | c.21343G>A p.D7115N (on ENST00000361203 / NM_001374722.1; = p.D4812N on NM_015548.5) | Missense Mutation (SNP) | VAF 19/230 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV55001679; called by muse, mutect2
- DYNC2H1 | c.1159C>T p.Q387* | Nonsense Mutation (SNP) | VAF 14/254 reads (6%) | catalogued as rs1350255711; called by muse, mutect2
- EDN2 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 85/428 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs926556784, COSV65423371; called by muse, mutect2, varscan2
- EPHA8 | c.2330C>G p.S777C | Missense Mutation (SNP) | VAF 36/578 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1165586714; called by muse, mutect2
- FBN1 | c.2971G>A p.E991K | Missense Mutation (SNP) | VAF 58/415 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as CD075404; called by muse, mutect2, varscan2
- FBXO11 | c.481G>C p.D161H (on ENST00000403359 / NM_001190274.2; = p.D77H on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/306 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57017676; called by muse, mutect2, varscan2
- FMN1 | c.568C>G p.L190V | Missense Mutation (SNP) | VAF 84/377 reads (22%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.023); catalogued as COSV100308750; called by muse, mutect2, varscan2
- GSTA2 | c.505G>C p.E169Q | Missense Mutation (SNP) | VAF 25/340 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101534061; called by muse, mutect2
- HECW2 | c.2269G>A p.E757K | Missense Mutation (SNP) | VAF 23/743 reads (3%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.027); catalogued as COSV99645913; called by muse, mutect2
- HK1 | c.2095G>A p.D699N | Missense Mutation (SNP) | VAF 22/824 reads (3%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as rs1383566248; called by muse, mutect2
- HK2 | c.11C>G p.S4W | Missense Mutation (SNP) | VAF 59/397 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.559); catalogued as COSV51878239, COSV51878851; called by muse, mutect2, varscan2
- IFIT2 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 33/305 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.417); catalogued as rs756283221; called by muse, mutect2, varscan2
- IFT88 | c.1465G>C p.D489H (on ENST00000319980 / NM_001318493.2; = p.D480H on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/271 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV60675967; called by muse, mutect2
- IGFBP1 | c.605A>C p.Y202S | Missense Mutation (SNP) | VAF 25/397 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1284303624; called by muse, mutect2
- IL18BP | c.234G>C p.L78= | Splice Region (SNP) | VAF 12/260 reads (5%) | catalogued as COSV52622003; called by muse, mutect2
- INSR | c.2981C>T p.S994F | Missense Mutation (SNP) | VAF 16/337 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57173643; called by muse, mutect2
- KCNS3 | c.1290G>C p.E430D | Missense Mutation (SNP) | VAF 38/353 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.156); catalogued as COSV100411157; called by muse, mutect2, varscan2
- LENG8 | c.1351C>T p.H451Y | Missense Mutation (SNP) | VAF 38/704 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.139); catalogued as rs1218174314; called by muse, mutect2
- LYPD3 | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 81/501 reads (16%) | catalogued as rs537767193; called by muse, mutect2, varscan2
- MAP3K12 | c.1687C>T p.R563C | Missense Mutation (SNP) | VAF 107/523 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.41); catalogued as rs560592149, COSV57231930; called by muse, mutect2, varscan2
- MARCHF10 | c.432G>C p.R144S | Missense Mutation (SNP) | VAF 77/413 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV60889568; called by muse, mutect2, varscan2
- MKRN3 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 12/395 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV58809475; called by muse, mutect2
- MROH2B | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 24/390 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV68187960; called by muse, mutect2
- MYOZ2 | c.188G>C p.R63T | Missense Mutation (SNP) | VAF 122/307 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61084162; called by muse, mutect2, varscan2
- NBEA | c.6342C>G p.F2114L | Missense Mutation (SNP) | VAF 29/282 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.069); catalogued as COSV59773024; called by muse, mutect2, varscan2
- NIN | c.5473C>T p.H1825Y (on ENST00000382041 / NM_182946.1; = p.H1112Y on NM_016350.4) | Missense Mutation (SNP) | VAF 41/340 reads (12%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.709); catalogued as rs371242462; called by muse, mutect2, varscan2
- NLRP8 | c.424C>G p.L142V | Missense Mutation (SNP) | VAF 33/254 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.694); catalogued as rs1397740229; called by muse, mutect2, varscan2
- OR52N1 | c.202C>G p.L68V | Missense Mutation (SNP) | VAF 67/324 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV100398717, COSV57693725; called by muse, mutect2, varscan2
- OTOF | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 83/436 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.079); catalogued as rs267599308, COSV99717312; called by muse, mutect2, varscan2
- PCDH15 | c.4942G>C p.E1648Q | Missense Mutation (SNP) | VAF 49/549 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV57387426; called by muse, mutect2
- PCLO | c.4297G>A p.E1433K | Missense Mutation (SNP) | VAF 78/359 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.058); catalogued as rs868651663; called by muse, mutect2, varscan2
- PHLPP2 | c.1447C>T p.R483W | Missense Mutation (SNP) | VAF 49/330 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs377712192; called by muse, mutect2, varscan2
- PLSCR2 | c.472C>G p.R158G (on ENST00000497985 / NM_001199978.1; = p.R85G on NM_020359.2) | Missense Mutation (SNP) | VAF 36/327 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV60859524; called by muse, mutect2, varscan2
- POLN | c.1807C>A p.L603I | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.134); catalogued as rs762219033; called by muse, mutect2, varscan2
- PRR14 | c.145C>G p.R49G | Missense Mutation (SNP) | VAF 30/471 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.518); catalogued as COSV54911134, COSV54911522; called by muse, mutect2
- PRSS16 | c.223C>T p.R75* | Nonsense Mutation (SNP) | VAF 44/289 reads (15%) | catalogued as rs551129446, COSV100041535; called by muse, mutect2, varscan2
- PUSL1 | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 103/469 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs772194557, COSV60087380; called by muse, mutect2, varscan2
- RAMP1 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 271/649 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.073); catalogued as rs757498337, COSV54538036; called by muse, mutect2, varscan2
- REM1 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 54/409 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs146287841; called by muse, mutect2, varscan2
- RNASE10 | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 61/431 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100116149; called by muse, mutect2, varscan2
- RNF17 | c.3611-1G>A p.X1204_splice | Splice Site (SNP) | VAF 17/100 reads (17%) | catalogued as COSV55035305; called by muse, mutect2, varscan2
- SECISBP2 | c.1201C>G p.P401A | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1289886306; called by muse, mutect2, varscan2
- SH2B2 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 82/507 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782076378; called by muse, mutect2, varscan2
- SLC35A2 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 117/403 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs1557042895; called by muse, mutect2, varscan2
- SRGAP3 | c.1893G>C p.M631I | Missense Mutation (SNP) | VAF 44/376 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV64533436; called by muse, mutect2, varscan2
- STUB1 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 29/463 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99555897; called by muse, mutect2
- SULF1 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 28/233 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as COSV52684833; called by muse, mutect2, varscan2
- TCF4 | c.130C>G p.Q44E | Missense Mutation (SNP) | VAF 51/454 reads (11%) | SIFT deleterious, low confidence (0); catalogued as COSV68175110; called by muse, mutect2, varscan2
- TCIRG1 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 12/387 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1423051176; called by muse, mutect2
- TDRD15 | c.2467C>G p.Q823E | Missense Mutation (SNP) | VAF 42/274 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.685); catalogued as COSV68267284; called by muse, mutect2, varscan2
- TEX43 | c.177C>G p.F59L | Missense Mutation (SNP) | VAF 13/232 reads (6%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.699); catalogued as COSV64036318; called by muse, mutect2
- TLL1 | c.814C>T p.Q272* | Nonsense Mutation (SNP) | VAF 30/135 reads (22%) | catalogued as COSV99286589; called by muse, mutect2, varscan2
- TRIM56 | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 55/326 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs762987156; called by muse, mutect2, varscan2
- UBE3D | c.826G>C p.D276H | Missense Mutation (SNP) | VAF 38/237 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1300059525; called by muse, mutect2, varscan2
- ZNF12 | c.1846C>T p.Q616* (on ENST00000405858 / NM_016265.4; = p.Q578* on NM_006956.3) | Nonsense Mutation (SNP) | VAF 65/370 reads (18%) | catalogued as COSV61245675; called by muse, mutect2, varscan2
- ZNF311 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 257/636 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as COSV65853071; called by muse, mutect2, varscan2
- ACVR1B | c.1076G>A p.R359H | Missense Mutation (SNP) | VAF 16/416 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADAMTSL4 | c.2290G>C p.E764Q | Missense Mutation (SNP) | VAF 88/667 reads (13%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- ADGRB3 | c.1697G>C p.R566T | Missense Mutation (SNP) | VAF 14/324 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- AGO3 | c.1273-1G>A p.X425_splice | Splice Site (SNP) | VAF 33/253 reads (13%) | called by muse, mutect2, varscan2
- AKR1B15 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 51/360 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ALS2 | c.961C>T p.Q321* | Nonsense Mutation (SNP) | VAF 34/240 reads (14%) | called by muse, mutect2, varscan2
- APBA1 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 156/683 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARAP2 | c.986C>G p.S329C | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2
- ARHGAP21 | c.968C>T p.S323L | Missense Mutation (SNP) | VAF 46/608 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); called by muse, mutect2
- ATG2A | c.2355G>C p.E785D | Missense Mutation (SNP) | VAF 17/302 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- BCORL1 | c.2117C>G p.S706* | Nonsense Mutation (SNP) | VAF 38/374 reads (10%) | called by muse, mutect2
- BICRAL | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 18/283 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- C8G | c.385G>C p.E129Q | Missense Mutation (SNP) | VAF 22/418 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); called by muse, mutect2
- CAGE1 | c.706G>C p.E236Q (on ENST00000512086; = p.E100Q on NM_205864.3) | Missense Mutation (SNP) | VAF 11/234 reads (5%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.948); called by muse, mutect2
- CCDC172 | c.76G>C p.E26Q | Missense Mutation (SNP) | VAF 75/372 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CCDC88C | c.1861G>C p.E621Q | Missense Mutation (SNP) | VAF 71/521 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- CDS2 | c.1012C>T p.H338Y | Missense Mutation (SNP) | VAF 28/427 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CELSR3 | c.2820G>T p.Q940H | Missense Mutation (SNP) | VAF 51/467 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CHEK2 | c.1049G>T p.G350V (on ENST00000382580 / NM_001005735.2; = p.G307V on NM_007194.4) | Missense Mutation (SNP) | VAF 50/321 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHRFAM7A | c.286G>C p.D96H | Missense Mutation (SNP) | VAF 72/657 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COL3A1 | c.3523G>C p.E1175Q | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.398); called by muse, mutect2
- COMMD1 | c.527C>G p.S176* | Nonsense Mutation (SNP) | VAF 34/237 reads (14%) | called by muse, varscan2
- CPVL | c.896C>G p.T299R | Missense Mutation (SNP) | VAF 60/194 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.543); called by muse, varscan2
- CRYBG3 | c.7540C>G p.H2514D | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- CUL9 | c.5404G>C p.E1802Q | Missense Mutation (SNP) | VAF 33/307 reads (11%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- CYBB | c.1453G>T p.E485* | Nonsense Mutation (SNP) | VAF 45/157 reads (29%) | called by muse, mutect2, varscan2
- DIAPH2 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 215/245 reads (88%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EDN3 | c.168G>C p.E56D | Missense Mutation (SNP) | VAF 107/697 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- EEF1A2 | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 46/478 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.471); called by muse, varscan2
- EEF1AKMT4-ECE2 | c.1485C>G p.I495M | Missense Mutation (SNP) | VAF 52/332 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- EEPD1 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 34/640 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0.039); called by muse, mutect2
- ELP1 | c.2084C>A p.S695* | Nonsense Mutation (SNP) | VAF 49/362 reads (14%) | called by muse, mutect2, varscan2
- ERBB4 | c.2878G>A p.D960N | Missense Mutation (SNP) | VAF 45/238 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- ERVFRD-1 | c.1372C>G p.Q458E | Missense Mutation (SNP) | VAF 55/461 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM47B | c.1243C>G p.P415A | Missense Mutation (SNP) | VAF 60/207 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- FERMT2 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 32/314 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GGT2 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by mutect2, varscan2
- GLI1 | c.2419G>A p.E807K | Missense Mutation (SNP) | VAF 72/535 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- GREM1 | c.142C>G p.Q48E | Missense Mutation (SNP) | VAF 119/695 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- HNRNPM | c.1172G>A p.G391E | Missense Mutation (SNP) | VAF 12/318 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.025); called by muse, mutect2
- IGSF22 | c.798G>A p.M266I | Missense Mutation (SNP) | VAF 26/370 reads (7%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.968); called by muse, mutect2
- INSRR | c.3777C>G p.F1259L | Missense Mutation (SNP) | VAF 209/485 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ISM2 | c.697C>G p.P233A | Missense Mutation (SNP) | VAF 17/476 reads (4%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- KANSL2 | c.614C>T p.S205L | Missense Mutation (SNP) | VAF 32/243 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- KDM7A | c.533C>G p.S178C | Missense Mutation (SNP) | VAF 39/273 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- KHDRBS1 | c.173C>A p.S58* | Nonsense Mutation (SNP) | VAF 26/868 reads (3%) | called by muse, mutect2
- KHDRBS2 | c.267G>C p.K89N | Missense Mutation (SNP) | VAF 94/255 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC9 | c.1952C>T p.S651L | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2
- MAD2L1BP | c.307C>G p.P103A | Missense Mutation (SNP) | VAF 30/304 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.416); called by muse, mutect2
- MKRN3 | c.891G>A p.M297I | Missense Mutation (SNP) | VAF 12/396 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- MYEF2 | c.1167G>A p.M389I | Missense Mutation (SNP) | VAF 15/434 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- N4BP2L1 | c.494C>G p.S165* | Nonsense Mutation (SNP) | VAF 13/279 reads (5%) | called by muse, mutect2
- NCAN | c.895G>C p.E299Q | Missense Mutation (SNP) | VAF 51/1076 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2
- NCBP1 | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 14/142 reads (10%) | called by muse, mutect2
- NIBAN1 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 29/604 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.118); called by muse, mutect2
- NIN | c.2170G>C p.E724Q | Missense Mutation (SNP) | VAF 42/594 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.139); called by muse, mutect2
- NUP160 | c.1933G>C p.D645H | Missense Mutation (SNP) | VAF 15/334 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); called by muse, mutect2
- OGDHL | c.2146G>C p.E716Q | Missense Mutation (SNP) | VAF 36/382 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- OR14J1 | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 66/427 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- OR2F1 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 52/400 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- OR5H8 | c.853C>G p.L285V | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious, low confidence (0.02); called by muse, mutect2, varscan2
- PC | c.134G>C p.R45T | Missense Mutation (SNP) | VAF 20/313 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- PEX2 | c.38G>C p.R13T | Missense Mutation (SNP) | VAF 71/376 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- PKHD1L1 | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- PPP2R1B | c.793G>C p.E265Q | Missense Mutation (SNP) | VAF 42/317 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PRKDC | c.6584C>A p.S2195* | Nonsense Mutation (SNP) | VAF 37/246 reads (15%) | called by muse, mutect2, varscan2
- PTGFR | c.97del p.S33Qfs*2 | Frame Shift Del (DEL) | VAF 154/360 reads (43%) | called by mutect2, varscan2
- RAB3IP | c.197C>T p.S66F (on ENST00000550536 / NM_175623.4; = p.S50F on NM_022456.5) | Missense Mutation (SNP) | VAF 61/387 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- RNF5 | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 38/526 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2
- RO60 | c.1345C>G p.L449V | Missense Mutation (SNP) | VAF 39/309 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RYR2 | c.12013G>A p.E4005K | Missense Mutation (SNP) | VAF 25/232 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SHPRH | c.4948G>A p.E1650K (on ENST00000275233 / NM_001042683.3; = p.E1654K on NM_173082.3) | Missense Mutation (SNP) | VAF 19/192 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.03); called by muse, mutect2
- SIAE | c.378G>C p.Q126H | Missense Mutation (SNP) | VAF 11/269 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SNX18 | c.451G>C p.D151H | Missense Mutation (SNP) | VAF 105/801 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STRC | c.4003G>A p.E1335K | Missense Mutation (SNP) | VAF 57/350 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- SYNM | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 54/818 reads (7%) | called by muse, mutect2
- TBC1D32 | c.2092C>T p.Q698* | Nonsense Mutation (SNP) | VAF 65/196 reads (33%) | called by muse, mutect2, varscan2
- TDRD15 | c.1066C>G p.L356V | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TEAD3 | c.40G>T p.E14* | Nonsense Mutation (SNP) | VAF 99/564 reads (18%) | called by muse, mutect2, varscan2
- TEK | c.538C>T p.H180Y | Missense Mutation (SNP) | VAF 18/456 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- TEP1 | c.7201G>C p.D2401H | Missense Mutation (SNP) | VAF 53/313 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- TEX51 | c.84G>C p.L28F | Missense Mutation (SNP) | VAF 29/580 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.608); called by muse, mutect2
- TEX51 | c.295G>A p.E99K (on ENST00000643416; = p.E81K on NM_001322244.2) | Missense Mutation (SNP) | VAF 18/301 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.783); called by muse, mutect2
- TMEFF1 | c.429C>G p.C143W | Missense Mutation (SNP) | VAF 32/222 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TPP2 | c.3703G>T p.E1235* | Nonsense Mutation (SNP) | VAF 13/310 reads (4%) | called by muse, mutect2
- TRIM24 | c.1833G>C p.L611F (on ENST00000343526 / NM_015905.3; = p.L577F on NM_003852.4) | Missense Mutation (SNP) | VAF 46/267 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TRPT1 | c.460C>T p.H154Y (on ENST00000317459 / NM_001160393.1; = p.H105Y on NM_031472.4) | Missense Mutation (SNP) | VAF 17/521 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TXNL4B | c.95G>A p.R32K | Missense Mutation (SNP) | VAF 33/314 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- UNC13A | c.1021G>C p.E341Q | Missense Mutation (SNP) | VAF 88/636 reads (14%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.11); called by muse, varscan2
- UQCC3 | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 18/444 reads (4%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2
- VWA8 | c.4087G>A p.E1363K | Missense Mutation (SNP) | VAF 58/273 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDFY4 | c.5985C>G p.V1995= | Splice Region (SNP) | VAF 60/309 reads (19%) | called by muse, mutect2, varscan2
- ZMYND19 | c.7G>C p.D3H | Missense Mutation (SNP) | VAF 42/394 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ZNF658 | c.2365G>C p.E789Q | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.048); called by mutect2, varscan2
- ZNF658 | c.2763G>C p.E921D | Missense Mutation (SNP) | VAF 73/401 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- ZW10 | c.1092C>G p.I364M | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- ABHD8 | c.942C>T p.F314= | Silent (SNP) | VAF 116/278 reads (42%) | catalogued as COSV56044054; called by muse, mutect2, varscan2
- AKAP8L | c.1236C>T p.F412= | Silent (SNP) | VAF 39/521 reads (7%) | called by muse, mutect2
- ANK3 | c.2445G>A p.L815= | Silent (SNP) | VAF 24/422 reads (6%) | called by muse, mutect2
- ATP8B2 | c.1059C>T p.F353= (on ENST00000672630; = p.F320= on NM_001005855.2) | Silent (SNP) | VAF 46/438 reads (11%) | catalogued as rs779262312, COSV59246147; called by muse, mutect2, varscan2
- CCDC88C | c.2721G>C p.L907= | Silent (SNP) | VAF 39/341 reads (11%) | called by muse, mutect2, varscan2
- CDH15 | c.675G>T p.V225= | Silent (SNP) | VAF 16/412 reads (4%) | called by muse, mutect2
- CDHR1 | c.1386C>G p.L462= | Silent (SNP) | VAF 70/722 reads (10%) | catalogued as COSV60559623; called by muse, mutect2
- COL11A1 | c.3306G>A p.G1102= | Silent (SNP) | VAF 39/327 reads (12%) | catalogued as COSV62176145; called by muse, mutect2, varscan2
- CRK | c.474C>T p.I158= | Silent (SNP) | VAF 59/438 reads (13%) | catalogued as rs1461532587; called by muse, mutect2, varscan2
- CTCF | c.1596C>T p.F532= | Silent (SNP) | VAF 19/657 reads (3%) | called by muse, mutect2
- DCAF12L1 | c.789C>G p.R263= | Silent (SNP) | VAF 21/409 reads (5%) | called by muse, mutect2
- E2F2 | c.543C>G p.L181= | Silent (SNP) | VAF 45/354 reads (13%) | called by muse, mutect2, varscan2
- ERBIN | c.1281C>T p.F427= | Silent (SNP) | VAF 40/240 reads (17%) | called by muse, mutect2, varscan2
- FGFR1 | c.1047C>T p.L349= (on ENST00000447712 / NM_023110.3; = p.L347= on NM_015850.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 44/450 reads (10%) | catalogued as COSV58334492; called by muse, mutect2
- FZD9 | c.1362C>T p.L454= | Silent (SNP) | VAF 24/622 reads (4%) | called by muse, mutect2
- G3BP1 | c.1026C>G p.L342= | Silent (SNP) | VAF 40/292 reads (14%) | called by muse, mutect2, varscan2
- GAL3ST2 | c.453C>T p.F151= | Silent (SNP) | VAF 26/793 reads (3%) | called by muse, mutect2
- HIP1 | c.588C>G p.L196= | Silent (SNP) | VAF 57/303 reads (19%) | catalogued as COSV61183173; called by muse, mutect2, varscan2
- HOXD4 | c.756G>A p.L252= | Silent (SNP) | VAF 69/305 reads (23%) | called by muse, mutect2, varscan2
- HPS1 | c.1782G>A p.Q594= | Silent (SNP) | VAF 46/401 reads (11%) | called by muse, mutect2, varscan2
- HSD11B1L | c.333C>G p.L111= | Silent (SNP) | VAF 65/577 reads (11%) | called by muse, mutect2, varscan2
- INSL3 | c.69C>T p.P23= | Silent (SNP) | VAF 143/827 reads (17%) | catalogued as COSV57953613; called by muse, mutect2, varscan2
- KDM3B | c.3693G>A p.Q1231= | Silent (SNP) | VAF 14/346 reads (4%) | called by muse, mutect2
- LPA | c.5805G>A p.R1935= | Silent (SNP) | VAF 69/332 reads (21%) | catalogued as rs775287178; called by muse, mutect2, varscan2
- LTBP3 | c.2982C>T p.I994= | Silent (SNP) | VAF 144/316 reads (46%) | called by muse, mutect2, varscan2
- MDGA2 | c.1254C>T p.I418= (on ENST00000399232 / NM_001113498.2; = p.I120= on NM_182830.4) | Silent (SNP) | VAF 108/268 reads (40%) | catalogued as rs367988985, COSV62087165; called by muse, mutect2, varscan2
- NOS1 | c.3156G>C p.L1052= | Silent (SNP) | VAF 22/636 reads (3%) | called by muse, mutect2
- OR2B6 | c.405C>T p.I135= | Silent (SNP) | VAF 61/346 reads (18%) | called by muse, mutect2, varscan2
- OR5B3 | c.237C>T p.V79= | Silent (SNP) | VAF 55/279 reads (20%) | called by muse, mutect2, varscan2
- PCDHGB6 | c.357C>T p.V119= | Silent (SNP) | VAF 164/411 reads (40%) | catalogued as rs1490844526; called by muse, mutect2, varscan2
- PDZD2 | c.8184G>A p.L2728= | Silent (SNP) | VAF 15/371 reads (4%) | called by muse, mutect2
- PPL | c.3933G>A p.L1311= | Silent (SNP) | VAF 54/624 reads (9%) | catalogued as COSV52169116; called by muse, mutect2
- PRELID2 | c.174C>T p.I58= (on ENST00000334744 / NM_182960.4; = p.I29= on NM_138492.6) | Silent (SNP) | VAF 61/189 reads (32%) | called by muse, mutect2, varscan2
- PRR7 | c.612C>G p.L204= | Silent (SNP) | VAF 25/889 reads (3%) | catalogued as COSV52788048; called by muse, mutect2
- PTPRU | c.2823C>T p.A941= | Silent (SNP) | VAF 150/373 reads (40%) | catalogued as rs374111722; called by muse, mutect2, varscan2
- SERPINA2 | c.897T>G p.L299= | Silent (SNP) | VAF 105/296 reads (35%) | called by muse, mutect2, varscan2
- SHC3 | c.585G>A p.A195= | Silent (SNP) | VAF 50/371 reads (13%) | catalogued as rs749464723; called by muse, mutect2, varscan2
- SLC26A1 | c.789C>T p.D263= | Silent (SNP) | VAF 131/643 reads (20%) | catalogued as rs972423931, COSV56105009; called by muse, mutect2, varscan2
- SPATA9 | c.498G>C p.L166= | Silent (SNP) | VAF 54/248 reads (22%) | called by muse, mutect2, varscan2
- TBCK | c.255G>A p.R85= | Silent (SNP) | VAF 28/225 reads (12%) | catalogued as rs373691598; called by muse, mutect2, varscan2
- TRIO | c.138C>T p.I46= | Silent (SNP) | VAF 43/269 reads (16%) | called by muse, mutect2, varscan2
- TTC16 | c.1173G>A p.A391= | Silent (SNP) | VAF 97/578 reads (17%) | catalogued as rs1432756708, COSV64779639; called by muse, mutect2, varscan2
- UBR4 | c.7863C>T p.F2621= | Silent (SNP) | VAF 22/532 reads (4%) | called by muse, mutect2
- UGT2A3 | c.549G>A p.G183= | Silent (SNP) | VAF 50/411 reads (12%) | catalogued as COSV52361541; called by muse, mutect2, varscan2
- ULBP3 | c.39C>T p.L13= | Silent (SNP) | VAF 59/459 reads (13%) | called by muse, mutect2, varscan2
- USP34 | c.9795G>A p.L3265= | Silent (SNP) | VAF 15/447 reads (3%) | called by muse, mutect2
- VSIG8 | c.858C>T p.L286= | Silent (SNP) | VAF 140/686 reads (20%) | catalogued as rs757568557, COSV100928801; called by muse, mutect2, varscan2
- WNK3 | c.5013A>G p.L1671= | Silent (SNP) | VAF 108/122 reads (89%) | called by muse, mutect2, varscan2
- ZBTB45 | c.1410G>A p.Q470= | Silent (SNP) | VAF 112/816 reads (14%) | called by muse, mutect2, varscan2
- CCR2 | c.941+64C>T | Intron (SNP) | VAF 44/297 reads (15%) | called by muse, mutect2, varscan2
- FBRS | chr16:30659589 G>T | 5'Flank (SNP) | VAF 48/288 reads (17%) | called by mutect2, varscan2
- FMR1 | c.51+532G>A | Intron (SNP) | VAF 22/191 reads (12%) | called by muse, mutect2, varscan2
- GOLGA3 | c.-124G>A | 5'UTR (SNP) | VAF 18/416 reads (4%) | called by muse, mutect2
- IGHV3-7 | chr14:106062150 ins GA | 3'Flank (INS) | VAF 51/102 reads (50%) | called by mutect2, pindel*
- KCNMA1 | c.378+813G>C | Intron (SNP) | VAF 77/734 reads (10%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+23217G>T | Intron (SNP) | VAF 37/336 reads (11%) | called by muse, mutect2, varscan2
- KCTD13 | c.414+139C>T | Intron (SNP) | VAF 38/512 reads (7%) | called by muse, mutect2
- MYCBPAP | c.76+314C>T | Intron (SNP) | VAF 66/463 reads (14%) | called by muse, mutect2, varscan2
- PIEZO2 | c.2493-403G>C | Intron (SNP) | VAF 23/232 reads (10%) | called by muse, mutect2, varscan2
- UNC13B | c.761+6289G>A | Intron (SNP) | VAF 8/170 reads (5%) | called by muse, mutect2
